RC case RC-B5DN — RC-PTCL: Refractory Cancers (RC) - Peripheral T-Cell Lymphoma (PTCL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature T- and NK-Cell Lymphomas; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/703c18e7-0920-4fd2-8050-33c062653096

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Year of birth: 1948; Vital status: Dead; Days to death: 597 days (1.6 years); Year of death: 2020.

Diagnoses (2)
1. Prolymphocytic leukemia, T-cell type (the primary disease): ICD-O-3 morphology code: 9834/3; ICD-10 code: C84; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Blood; Classification of tumor: primary; Age at diagnosis: 70.5 years (25,751 days); Year of diagnosis: 2019; Method of diagnosis: Blood Draw; Ann Arbor B symptoms: Yes; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Ann arbor b symptoms described array: Weight Loss / Night Sweats; Ann Arbor extranodal involvement: Yes; International Prognostic Index (IPI): High-Intermediate Risk; Sites of involvement: Bone marrow / Peripheral blood.
   Pathology details: Bone marrow malignant cells: Yes; Timepoint category: Initial Diagnosis.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Alemtuzumab; Initial disease status: Initial Diagnosis; Days to treatment start: 34 days; Days to treatment end: 111 days; Treatment outcome: Complete Response; Reason treatment ended: Course of Therapy Completed; Timepoint category: First Treatment; Treatment effect indicator: Yes.
   Treatment given: Treatment type: Stem Cell Transplantation, Allogeneic; Days to treatment start: 153 days; Treatment outcome: Complete Response; Treatment effect indicator: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Ruxolitinib; Initial disease status: Progressive Disease; Days to treatment start: 545 days (1.5 years); Days to treatment end: 583 days (1.6 years); Reason treatment ended: Death; Clinical trial indicator: Yes; Timepoint category: Post Initial Treatment.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Complete Response; Timepoint category: Postoperative.
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Complete Response; Timepoint category: Postoperative.
   Recorded as not given: Organ Transplantation; Stem Cell Transplantation, Allogeneic; Stem Cell Transplantation, Autologous; Stem Cell Transplantation, NOS.
2. Recurrence (histology not recorded by GDC). Age at diagnosis: 71.6 years (26,152 days); Days to diagnosis: 401 days (1.1 years).

Follow-up (4 entries)
- Day 0 (initial diagnosis): Karnofsky performance status: 90.
- Days to follow up: 101 days; Disease response: Tumor Free.
- Day 401 (recurrence): Progression or recurrence: Yes; Days to recurrence: 401 days (1.1 years).
- Follow-up contacts recording only the day: day 231, day 597.

Molecular and laboratory tests
- Lactate Dehydrogenase 432 U/L [Blood test normal range upper: 250].

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 56.2 kg; Height: 166 cm; BMI: 20.4.
- Timepoint category: Prior to Diagnosis; Comorbidities: Hypertension / Osteoporosis or Osteopenia.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Family history
- Relative with cancer history: yes; Relationship type: Father; Relationship primary diagnosis: Lung Cancer.
- Relative with cancer history: yes; Relationship type: Brother; Relationship primary diagnosis: Head and Neck Cancer.
- Relative with cancer history: yes; Relationship type: Sister; Relationship primary diagnosis: Lung Cancer.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample RC-B5DN-NB1-A: Tissue type: Normal; Specimen type: Granulocytes; Preservation method: Frozen. An open-access masked somatic mutation file (MAF) exists for this specimen and lists no variants.
- Sample RC-B5DN-TBP1-A: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Preservation method: Frozen. An open-access masked somatic mutation file (MAF) exists for this specimen and lists no variants.
  Slide RC-B5DN-TBP1-A-1-0-CS2: Section location: Top; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 0; Percent necrosis: 100; Percent stromal cells: 0; Percent lymphocyte infiltration: 90; Percent monocyte infiltration: 5; Percent neutrophil infiltration: 5.
